Somatic mutation profile of tumor specimen TCGA-A3-3346-01A (aliquot TCGA-A3-3346-01A-01W-0886-08) from TCGA case TCGA-A3-3346, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 68.8 years (25,118 days).
Specimen TCGA-A3-3346-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d9ef999-4f49-4dee-9bdb-0862325ad77e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3346-11A (Solid Tissue Normal), aliquot TCGA-A3-3346-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df87f4af-6ce2-4e81-9ef7-22f755b43088

The open-access MAF lists 185 somatic variants for this specimen: 132 protein-altering or splice-affecting, 52 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 52, Nonsense Mutation 11, Frame Shift Del 8, Frame Shift Ins 6, Splice Site 5, In Frame Del 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 31/227 reads (14%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.405dup p.C136Mfs*44 | Frame Shift Ins (INS) | VAF 134/325 reads (41%) | catalogued as rs398123323, CI110210, COSV64293934; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC4 | c.872G>A p.W291* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV65316134; called by muse, mutect2
- ADPRHL1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.492); catalogued as rs774575530; called by muse, mutect2
- ANXA4 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.642); catalogued as COSV67848612; called by muse, mutect2, varscan2
- ASAP2 | c.2522C>A p.P841H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.315); catalogued as COSV55635888; called by muse, mutect2, varscan2
- ATP4A | c.1761G>A p.M587I | Missense Mutation (SNP) | VAF 14/395 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.123); catalogued as COSV52870215; called by muse, mutect2
- ATP5F1B | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51640683; called by muse, mutect2, varscan2
- CCHCR1 | c.1925G>T p.R642L | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV52536163; called by muse, mutect2, varscan2
- CELA3B | c.107T>A p.V36D | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV61404915; called by muse, mutect2, varscan2
- CHKB | c.678-1G>A p.X226_splice | Splice Site (SNP) | VAF 18/142 reads (13%) | catalogued as COSV100376773, COSV56418046; called by muse, mutect2, varscan2
- COL6A3 | c.8932G>A p.A2978T | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs760847135, COSV55087300; called by muse, mutect2, varscan2
- COL6A6 | c.2168G>A p.R723K | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV62032119; called by muse, mutect2, varscan2
- CPSF4 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV52858584; called by muse, mutect2
- CRTC1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV58721391; called by muse, mutect2
- DCDC2 | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as COSV101015519, COSV65829438; called by muse, mutect2, varscan2
- DENND2C | c.2392C>T p.R798* (on ENST00000393274 / NM_001256404.2; = p.R741* on NM_198459.4) | Nonsense Mutation (SNP) | VAF 29/177 reads (16%) | catalogued as rs866481620, COSV67923051; called by muse, mutect2, varscan2
- DENND2D | c.818C>A p.A273D | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62959684; called by muse, mutect2, varscan2
- DENND4B | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.452); catalogued as COSV57844459; called by muse, mutect2, varscan2
- DHX8 | c.2425A>G p.I809V | Missense Mutation (SNP) | VAF 129/251 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.735); catalogued as COSV52255179; called by muse, mutect2, varscan2
- DUOX1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV58484486; called by muse, mutect2
- E2F7 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV59742083; called by muse, mutect2, varscan2
- EEF1E1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1003835058, COSV65675883; called by muse, mutect2
- ESPL1 | c.5278A>T p.I1760F | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV57761395; called by muse, mutect2, varscan2
- FANCA | c.2054G>A p.R685K | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1183781456, COSV66882854; called by muse, mutect2, varscan2
- FMO5 | c.995A>T p.Y332F | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54209137; called by muse, mutect2
- GGA1 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57330686, COSV57331127; called by muse, mutect2
- GON4L | c.1789-2A>C p.X597_splice | Splice Site (SNP) | VAF 86/250 reads (34%) | catalogued as COSV55197638; called by muse, mutect2
- GPRIN3 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 18/191 reads (9%) | catalogued as rs1024549870, COSV60885406, COSV60885712; called by muse, varscan2
- GTF2H1 | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV56379408; called by muse, varscan2
- H2AC15 | c.235A>C p.I79L | Missense Mutation (SNP) | VAF 113/186 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV57585618, COSV57586179; called by muse, mutect2, varscan2
- HELZ | c.3439G>A p.V1147I | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as rs1309310591; called by muse, mutect2
- HIVEP1 | c.2420C>T p.S807F | Missense Mutation (SNP) | VAF 24/315 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65103733; called by muse, mutect2
- HIVEP2 | c.6056C>G p.P2019R | Missense Mutation (SNP) | VAF 389/674 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50030893; called by muse, mutect2, varscan2
- HOXC6 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV54537752; called by muse, mutect2, varscan2
- IFT172 | c.2428del p.E810Nfs*30 | Frame Shift Del (DEL) | VAF 130/392 reads (33%) | catalogued as rs1423464068; called by mutect2, pindel, varscan2
- IL1RAPL1 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56303463; called by mutect2, varscan2
- IPO4 | c.2804A>C p.Q935P | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV61017638; called by muse, mutect2, varscan2
- ITPRID2 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV57474658; called by muse, mutect2, varscan2
- IZUMO2 | c.599T>G p.F200C | Missense Mutation (SNP) | VAF 144/381 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV53230838; called by muse, mutect2, varscan2
- KBTBD7 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.063); catalogued as COSV65266905; called by muse, mutect2, varscan2
- KCTD18 | c.1111C>G p.P371A | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV63344872; called by muse, mutect2, varscan2
- KIAA1522 | c.2843C>T p.S948L (on ENST00000373480 / NM_001198972.2; = p.S1007L on NM_020888.3) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53866606; called by muse, mutect2, varscan2
- KIAA1614 | c.1775A>C p.E592A | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV62551411; called by muse, mutect2, varscan2
- LARP1 | c.1513T>A p.F505I (on ENST00000518297 / NM_033551.3; = p.F428I on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 162/806 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60429705; called by muse, mutect2, varscan2
- LCN1 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55018910; called by muse, mutect2, varscan2
- LHX4 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 98/1500 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV55372954; called by muse, mutect2
- MAP3K1 | c.3334G>A p.V1112M | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV68125706; called by muse, mutect2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 24/122 reads (20%) | catalogued as rs777328830; called by mutect2, varscan2
- MARK1 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65069808; called by muse, mutect2, varscan2
- MDH1 | c.923T>A p.F308Y | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51864353; called by muse, mutect2, varscan2
- MIER1 | c.1277T>G p.I426S (on ENST00000355356 / NM_001077701.3; = p.I443S on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV62531228; called by muse, mutect2, varscan2
- MINDY4 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 382/1773 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1444646630, COSV54672919, COSV54676651; called by muse, mutect2, varscan2
- MTMR3 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1405450338, COSV60302019, COSV60306149; called by muse, mutect2, varscan2
- MTOR | c.6638C>T p.P2213L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV63875502; called by muse, mutect2, varscan2
- NAT2 | c.730T>C p.F244L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV54062579; called by muse, mutect2, varscan2
- NCOA5 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 212/631 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51646049; called by muse, mutect2, varscan2
- NLRP12 | c.3096C>T p.L1032= | Splice Region (SNP) | VAF 13/101 reads (13%) | catalogued as COSV60751450, COSV60751504; called by muse, mutect2, varscan2
- NOBOX | c.838C>G p.R280G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56196400, COSV99779790; called by muse, mutect2, varscan2
- NRP2 | c.1991G>A p.W664* | Nonsense Mutation (SNP) | VAF 12/260 reads (5%) | catalogued as COSV55932311; called by muse, mutect2
- OSBPL2 | c.1010G>A p.G337E (on ENST00000313733 / NM_144498.4; = p.G325E on NM_014835.4) | Missense Mutation (SNP) | VAF 115/250 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58218603; called by muse, varscan2
- PCDHGB3 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs757971401, COSV53995211; called by muse, mutect2, varscan2
- PDXP | c.569C>G p.T190S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV53216994; called by muse, mutect2, varscan2
- PIP | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 193/724 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV52121156; called by muse, mutect2, varscan2
- PITRM1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 113/184 reads (61%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs752614003, COSV56536213; called by muse, mutect2, varscan2
- PLA2G15 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.108); catalogued as COSV54723919; called by muse, mutect2, varscan2
- POLQ | c.6721C>T p.R2241* | Nonsense Mutation (SNP) | VAF 86/114 reads (75%) | catalogued as rs369712134, COSV51745891, COSV51764424; called by muse, mutect2, varscan2
- PPFIA2 | c.3079G>A p.E1027K | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV61033054; called by muse, mutect2, varscan2
- PPWD1 | c.88A>T p.R30* | Nonsense Mutation (SNP) | VAF 85/202 reads (42%) | catalogued as COSV54334693; called by muse, mutect2, varscan2
- PRELID1 | c.453C>G p.F151L | Missense Mutation (SNP) | VAF 122/250 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs747443529, COSV57463814; called by muse, mutect2, varscan2
- RAI2 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 59/1176 reads (5%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.033); catalogued as COSV58965574; called by muse, mutect2
- RARA | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 79/97 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV54194947; called by muse, mutect2, varscan2
- RCAN1 | c.482T>A p.L161Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58251070; called by muse, mutect2, varscan2
- RFX7 | c.1843G>A p.A615T (on ENST00000559447 / NM_001368074.1; = p.A712T on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.196); catalogued as COSV57966697; called by muse, mutect2, varscan2
- RYR2 | c.13232C>T p.P4411L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs1482281708, COSV63701380; called by muse, mutect2
- S100A14 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV59884969; called by muse, mutect2, varscan2
- SECISBP2L | c.2364_2365insA p.V789Sfs*2 (on ENST00000559471 / NM_001193489.2; = p.V744Sfs*2 on NM_014701.4) | Frame Shift Ins (INS) | VAF 127/469 reads (27%) | catalogued as COSV99960408; called by mutect2, pindel, varscan2
- SEPTIN10 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 12/357 reads (3%) | catalogued as COSV61779407; called by muse, mutect2
- SERPINB7 | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60535045; called by muse, mutect2, varscan2
- SF3B3 | c.3449C>T p.S1150F | Missense Mutation (SNP) | VAF 20/490 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV56789686; called by muse, mutect2
- SLC11A1 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as rs749299062, COSV51918392; called by mutect2, varscan2
- SLC15A2 | c.1961C>A p.A654E | Missense Mutation (SNP) | VAF 22/514 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV55199621; called by muse, mutect2
- SLC66A3 | c.323C>A p.A108D | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV54467764; called by muse, mutect2, varscan2
- SMAD9 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1483291649, COSV63205115, COSV63205817; called by muse, mutect2, varscan2
- SMC2 | c.1967T>A p.V656E | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV53962063; called by muse, mutect2, varscan2
- ST6GAL2 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 25/82 reads (30%) | PolyPhen probably damaging (0.967); catalogued as COSV64528016; called by muse, mutect2, varscan2
- SYNE1 | c.20199+1G>A p.X6733_splice (on ENST00000367255 / NM_182961.4; = p.X6662_splice on NM_033071.3) | Splice Site (SNP) | VAF 37/119 reads (31%) | catalogued as COSV55047339; called by muse, mutect2, varscan2
- SYT17 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV62545138, COSV62547384; called by muse, mutect2
- TBC1D2B | c.1229G>A p.S410N | Missense Mutation (SNP) | VAF 116/929 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56044656; called by muse, mutect2, varscan2
- TCEANC2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV52370877; called by muse, mutect2, varscan2
- TET2 | c.1800G>A p.M600I | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54423916, COSV54439146; called by muse, mutect2
- THOC2 | c.3186+2T>C p.X1062_splice | Splice Site (SNP) | VAF 90/134 reads (67%) | catalogued as COSV55551569; called by muse, mutect2, varscan2
- THYN1 | c.617A>G p.Q206R | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV55541679; called by muse, mutect2
- TLN2 | c.2291G>C p.S764T | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV60892822; called by muse, mutect2, varscan2
- TMEM116 | c.17G>C p.S6T | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as COSV61393212; called by muse, mutect2
- TMEM131 | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV51782028; called by muse, mutect2, varscan2
- TONSL | c.932T>A p.M311K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV68048927; called by muse, mutect2, varscan2
- TP53 | c.533dup p.H178Qfs*3 | Frame Shift Ins (INS) | VAF 98/206 reads (48%) | catalogued as COSV53370106; called by mutect2, pindel, varscan2
- TUBA4A | c.148A>C p.T50P | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV50280007; called by muse, mutect2, varscan2
- TXNDC15 | c.808G>C p.G270R | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64379962; called by muse, mutect2, varscan2
- TXNDC15 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64379970; called by muse, mutect2, varscan2
- UBP1 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV52146799; called by muse, mutect2
- USP26 | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 94/143 reads (66%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.894); catalogued as COSV63709296; called by muse, mutect2, varscan2
- WDR19 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as COSV56468019; called by muse, mutect2, varscan2
- ZMYM6 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58185001; called by muse, mutect2, varscan2
- ZNF318 | c.5644G>A p.D1882N | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.385); catalogued as COSV58935309; called by muse, mutect2
- ZNF511 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62920410; called by mutect2, varscan2
- ZYG11B | c.1061T>A p.V354E | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV53755310; called by muse, varscan2
- AHNAK2 | c.459_463delinsAAAAA p.R154_E155delinsKK | Missense Mutation (ONP) | VAF 5/43 reads (12%) | called by muse*, pindel
- ALG10B | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 13/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALG10B | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCT8L2 | c.701C>G p.T234R | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); called by mutect2, varscan2
- CERCAM | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DNM1L | c.406del p.S136Hfs*7 | Frame Shift Del (DEL) | VAF 80/214 reads (37%) | called by mutect2, pindel, varscan2
- FAM161B | c.1578_1583delinsCTG p.E526_A528delinsD* (on ENST00000651776; = p.E463_A465delinsD* on NM_152445.3) | Nonsense Mutation (DEL) | VAF 106/242 reads (44%) | called by pindel, varscan2*
- KCNH7 | c.2614-2del p.X872_splice | Splice Site (DEL) | VAF 51/184 reads (28%) | called by mutect2, pindel, varscan2
- NUDT16 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.202); called by muse, mutect2
- PADI3 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 34/310 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PARD6B | c.813_814del p.N271Kfs*10 | Frame Shift Del (DEL) | VAF 111/343 reads (32%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3879del p.K1293Nfs*20 (on ENST00000296302 / NM_001366071.2; = p.K1268Nfs*20 on NM_018313.5) | Frame Shift Del (DEL) | VAF 91/155 reads (59%) | called by mutect2, pindel, varscan2
- PCDH11Y | c.1726G>A p.D576N (on ENST00000400457 / NM_032973.2; = p.D565N on NM_032971.3) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PSMG1 | c.621del p.E207Dfs*5 | Frame Shift Del (DEL) | VAF 22/127 reads (17%) | called by mutect2, pindel, varscan2
- RASGRP1 | c.39del p.K13Nfs*14 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- RIOX2 | c.895G>A p.E299K (on ENST00000333396 / NM_001042533.2; = p.E298K on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.122); called by muse, mutect2
- SCYL2 | c.2785G>A p.G929R | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYNRG | c.3931C>A p.P1311T | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TG | c.4024_4038del p.V1342_V1346del | In Frame Del (DEL) | VAF 210/675 reads (31%) | called by mutect2, pindel, varscan2
- TMCC3 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 158/1112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TMEM68 | c.292dup p.T98Nfs*14 | Frame Shift Ins (INS) | VAF 210/609 reads (34%) | called by mutect2, pindel, varscan2
- TMPRSS6 | c.1753del p.L585Sfs*19 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- ZBTB21 | c.3107_3115del p.A1036_F1039delinsV | In Frame Del (DEL) | VAF 27/106 reads (25%) | called by mutect2, pindel, varscan2
- ZNF846 | c.603del p.D202Tfs*16 | Frame Shift Del (DEL) | VAF 46/113 reads (41%) | called by mutect2, pindel, varscan2
- ABHD14A-ACY1 | c.156G>A p.S52= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as rs201635694, COSV56473154; called by muse, mutect2, varscan2
- ABL1 | c.1944C>T p.F648= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, varscan2
- ACOX2 | c.261C>T p.I87= | Silent (SNP) | VAF 26/238 reads (11%) | catalogued as COSV57150062; called by muse, mutect2, varscan2
- ADAMTS18 | c.3081C>T p.P1027= | Silent (SNP) | VAF 36/322 reads (11%) | catalogued as rs373173918; called by muse, varscan2
- ALOX12B | c.21G>A p.R7= | Silent (SNP) | VAF 77/150 reads (51%) | catalogued as rs1402507687, COSV59874872; called by muse, mutect2, varscan2
- ARSJ | c.894C>T p.S298= | Silent (SNP) | VAF 22/183 reads (12%) | catalogued as rs934327869, COSV59539004; called by muse, mutect2, varscan2
- ASB13 | c.510C>T p.L170= | Silent (SNP) | VAF 28/246 reads (11%) | catalogued as rs1486835601, COSV63091680; called by muse, varscan2
- ATP7B | c.1084C>T p.L362= | Silent (SNP) | VAF 28/258 reads (11%) | catalogued as COSV54435571; called by muse, varscan2
- ATP9B | c.1854C>T p.P618= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV56957210; called by muse, mutect2, varscan2
- BCAT1 | c.762G>A p.Q254= | Silent (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- BMPR2 | c.2916G>A p.K972= | Silent (SNP) | VAF 25/77 reads (32%) | called by mutect2, varscan2
- BSCL2 | c.1119C>T p.A373= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV54016889; called by muse, mutect2
- CHST8 | c.234C>T p.D78= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV52861297; called by muse, mutect2, varscan2
- CLASP2 | c.594G>T p.V198= | Silent (SNP) | VAF 81/172 reads (47%) | catalogued as COSV56289273; called by muse, mutect2, varscan2
- CWF19L1 | c.723C>T p.F241= | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as COSV62499604; called by muse, mutect2, varscan2
- CXorf65 | c.525C>G p.L175= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV52149570; called by muse, mutect2
- DAP3 | c.333C>T p.Y111= | Silent (SNP) | VAF 97/541 reads (18%) | catalogued as COSV58021998; called by muse, mutect2, varscan2
- DENND2D | c.819T>G p.A273= | Silent (SNP) | VAF 53/156 reads (34%) | catalogued as COSV62959665; called by muse, mutect2, varscan2
- DIP2B | c.1587T>C p.V529= | Silent (SNP) | VAF 164/328 reads (50%) | catalogued as COSV56588659; called by muse, mutect2, varscan2
- DNAJC1 | c.1197C>T p.P399= | Silent (SNP) | VAF 8/185 reads (4%) | catalogued as COSV65412705; called by muse, mutect2
- FER1L6 | c.3063C>T p.C1021= | Silent (SNP) | VAF 100/257 reads (39%) | catalogued as rs369624500, COSV67548672; called by muse, mutect2, varscan2
- FSIP1 | c.48A>T p.S16= | Silent (SNP) | VAF 67/159 reads (42%) | catalogued as COSV63225965; called by muse, mutect2, varscan2
- FXYD2 | c.168G>A p.K56= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs750019905, COSV52642554; called by muse, mutect2
- H1-0 | c.423C>A p.T141= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs370894514, COSV50649701; called by muse, mutect2, varscan2
- HDAC1 | c.921C>T p.N307= | Silent (SNP) | VAF 82/250 reads (33%) | catalogued as rs780243739, COSV61482250; called by muse, mutect2, varscan2
- IGSF6 | c.411C>T p.T137= | Silent (SNP) | VAF 76/457 reads (17%) | catalogued as COSV51679810; called by muse, varscan2
- IL7R | c.444G>T p.V148= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV57411144; called by muse, mutect2, varscan2
- INTS2 | c.24A>C p.I8= | Silent (SNP) | VAF 47/55 reads (85%) | catalogued as COSV52155215; called by muse, varscan2
- IRF9 | c.615G>A p.Q205= | Silent (SNP) | VAF 438/970 reads (45%) | catalogued as COSV60703690; called by muse, varscan2
- LILRB5 | c.1083C>G p.A361= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV60259764; called by muse, varscan2
- LRP2 | c.4137C>T p.F1379= | Silent (SNP) | VAF 52/292 reads (18%) | catalogued as COSV55564998, COSV55567061; called by muse, mutect2, varscan2
- MED12L | c.2796C>T p.L932= | Silent (SNP) | VAF 52/608 reads (9%) | catalogued as COSV56388854; called by muse, mutect2
- MT1X | c.84C>T p.S28= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV66777932; called by muse, mutect2
- MYO5A | c.3444A>C p.V1148= | Silent (SNP) | VAF 66/198 reads (33%) | catalogued as COSV62562800; called by muse, mutect2, varscan2
- NAV2 | c.2511C>T p.I837= (on ENST00000396087 / NM_001244963.2; = p.I814= on NM_145117.5) | Silent (SNP) | VAF 34/432 reads (8%) | catalogued as COSV62329217; called by muse, mutect2
- NUAK2 | c.1506C>T p.L502= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as rs1341877488, COSV65682173; called by muse, mutect2
- NUP35 | c.447A>C p.T149= | Silent (SNP) | VAF 42/153 reads (27%) | catalogued as COSV54558749; called by muse, mutect2, varscan2
- OR1L1 | c.768C>T p.V256= (on ENST00000373686; = p.V206= on NM_001005236.3) | Silent (SNP) | VAF 512/793 reads (65%) | catalogued as COSV58936109; called by muse, mutect2, varscan2
- ORC1 | c.1476A>T p.R492= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV65364634; called by muse, mutect2, varscan2
- PADI3 | c.69G>A p.V23= | Silent (SNP) | VAF 33/313 reads (11%) | catalogued as COSV100968494; called by muse, mutect2, varscan2
- PCDHGA11 | c.570C>T p.A190= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV53995232; called by muse, mutect2, varscan2
- RASSF6 | c.846T>A p.I282= (on ENST00000342081 / NM_201431.2; = p.I250= on NM_177532.5) | Silent (SNP) | VAF 271/596 reads (45%) | catalogued as COSV56720018; called by muse, mutect2, varscan2
- RBM47 | c.1593T>C p.I531= (on ENST00000295971 / NM_001098634.2; = p.I462= on NM_019027.4) | Silent (SNP) | VAF 37/203 reads (18%) | catalogued as COSV55939555; called by muse, mutect2, varscan2
- RIOX2 | c.894G>A p.V298= (on ENST00000333396 / NM_001042533.2; = p.V297= on NM_032778.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- SPEN | c.10806C>T p.Y3602= | Silent (SNP) | VAF 40/228 reads (18%) | catalogued as COSV65270922; called by muse, varscan2
- SPZ1 | c.603C>T p.N201= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as COSV57064271; called by muse, mutect2, varscan2
- TACC2 | c.615C>T p.L205= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV57765142; called by muse, mutect2, varscan2
- TBX3 | c.93C>T p.S31= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV57473940; called by muse, mutect2, varscan2
- TMCC3 | c.1290C>T p.S430= | Silent (SNP) | VAF 158/1105 reads (14%) | catalogued as rs960003369; called by muse, mutect2, varscan2
- TMPRSS15 | c.2412T>C p.Y804= | Silent (SNP) | VAF 37/195 reads (19%) | catalogued as rs760633326, COSV53044814; called by muse, mutect2, varscan2
- VPS26A | c.429G>A p.L143= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV54968875; called by muse, mutect2, varscan2
- VPS35 | c.1518G>A p.Q506= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV54480150; called by muse, mutect2
- NFRKB | c.641-18_641-17insGTACGAAGGGGCAGTGCGGTAAGCGG | Intron (INS) | VAF 5/36 reads (14%) | called by mutect2, varscan2*
